Somatic mutation profile of cancer-model specimen HCM-SANG-0289-C15-85A (3D Organoid; aliquot HCM-SANG-0289-C15-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0289-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0289-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bb0aa47-4a6e-4b76-86eb-dda5b27a5305.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0289-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0289-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59c6ef1a-54f4-4a33-9eee-fd26032d740f

The open-access MAF lists 265 somatic variants for this specimen: 194 protein-altering or splice-affecting, 56 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 56, Intron 9, Nonsense Mutation 8, Frame Shift Del 5, 3'UTR 4, Frame Shift Ins 2, 5'Flank 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 79/404 reads (20%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 151/409 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM7 | c.1468T>G p.F490V | Missense Mutation (SNP) | VAF 30/550 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.763); catalogued as COSV51546920; called by muse, mutect2
- ADD2 | c.928C>A p.Q310K | Missense Mutation (SNP) | VAF 148/281 reads (53%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.561); catalogued as COSV52469610; called by muse, mutect2, varscan2
- ADNP | c.1823C>A p.S608* | Nonsense Mutation (SNP) | VAF 43/516 reads (8%) | catalogued as COSV100823598; called by muse, mutect2
- ADRA1B | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 155/519 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs749687924; called by muse, mutect2, varscan2
- AKR1D1 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV54341286; called by muse, mutect2
- ANKRD52 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 36/477 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs780784772; called by muse, mutect2
- APBA2 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 73/893 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs766126956; called by muse, mutect2
- ARHGAP24 | c.1495C>T p.R499* (on ENST00000395184 / NM_001025616.3; = p.R406* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 141/490 reads (29%) | catalogued as COSV51987040; called by muse, mutect2, varscan2
- ARHGEF7 | c.1979C>A p.P660H (on ENST00000375741 / NM_001113511.2; = p.P482H on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 244/672 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99522311; called by muse, mutect2, varscan2
- ARID1A | c.5138del p.L1713Qfs*5 | Frame Shift Del (DEL) | VAF 86/158 reads (54%) | catalogued as COSV61374077, COSV61380164; called by mutect2, pindel, varscan2
- ARMC8 | c.1073G>A p.R358H (on ENST00000469044 / NM_001363941.2; = p.R344H on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1420982397, COSV61768165; called by muse, mutect2
- ARPP21 | c.1201A>G p.S401G | Missense Mutation (SNP) | VAF 117/229 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs1196024489; called by muse, mutect2, varscan2
- ASTN1 | c.1345T>G p.F449V | Missense Mutation (SNP) | VAF 247/472 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV56087061; called by muse, mutect2, varscan2
- ASTN2 | c.2282A>G p.K761R (on ENST00000313400 / NM_001365069.1; = p.K710R on NM_014010.5) | Missense Mutation (SNP) | VAF 229/491 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs974202503, COSV100524865, COSV100531251; called by muse, mutect2, varscan2
- AXIN2 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 67/860 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.454); catalogued as rs774732785, COSV61056046; ClinVar: uncertain significance; called by muse, mutect2
- BCAS3 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 13/381 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101175609; called by muse, mutect2
- BOC | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 30/620 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); catalogued as rs771932279, COSV99847793; called by muse, mutect2
- BPIFA2 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 134/369 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs746002310; called by muse, mutect2, varscan2
- C1QTNF4 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 82/656 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.733); catalogued as rs1233944244; called by muse, varscan2
- C4orf54 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 62/780 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV101552090; called by muse, mutect2
- CA14 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 133/373 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs782018971; called by muse, mutect2, varscan2
- CASKIN1 | c.3505G>A p.V1169M | Missense Mutation (SNP) | VAF 246/710 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs1458576669; called by muse, mutect2, varscan2
- CFAP94 | c.1184C>T p.P395L (on ENST00000320267 / NM_001352064.2; = p.P401L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212735703; called by muse, mutect2, varscan2
- CNTN1 | c.2454A>C p.K818N | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV100751778, COSV61641701; called by muse, mutect2, varscan2
- CNTNAP5 | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 30/498 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV70488253; called by muse, mutect2
- CYLC1 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV61411679, COSV61416457; called by muse, mutect2, varscan2
- DDO | c.737C>T p.P246L (on ENST00000368924 / NM_001368172.1; = p.P187L on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 173/496 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.304); catalogued as rs778718857, COSV64470557; called by muse, mutect2, varscan2
- DDX58 | c.2237G>C p.G746A | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs1437935687; called by muse, mutect2, varscan2
- DGKQ | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 340/668 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1291917906; called by muse, mutect2, varscan2
- DNAH9 | c.6242A>G p.K2081R | Missense Mutation (SNP) | VAF 278/520 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as rs752058038; called by muse, mutect2, varscan2
- DOHH | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 165/513 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV99171028; called by muse, mutect2, varscan2
- DSTYK | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 127/311 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs562238251; called by muse, mutect2, varscan2
- ELAVL3 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1358223556; called by muse, mutect2
- ENTHD1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 207/436 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762245558, COSV100288271; called by muse, mutect2, varscan2
- EPHA5 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 136/389 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201120003, COSV56641766; called by muse, mutect2, varscan2
- EZH1 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 155/406 reads (38%) | catalogued as COSV70549311; called by muse, mutect2, varscan2
- FAM13A | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 86/302 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771172333; called by muse, mutect2, varscan2
- FAM81A | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 28/355 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs764318600, COSV55680175; called by muse, mutect2
- FBLN2 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 230/736 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.466); catalogued as rs760367076; called by muse, mutect2, varscan2
- FLG | c.7534A>C p.S2512R | Missense Mutation (SNP) | VAF 217/490 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs773788883, COSV64241812, COSV64245918; called by muse, mutect2, varscan2
- FLNA | c.6019G>A p.V2007M (on ENST00000369850 / NM_001110556.2; = p.V1999M on NM_001456.3) | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs200956777, COSV61042743; called by muse, mutect2, varscan2
- FMN2 | c.3938T>G p.L1313R | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV60421040; called by muse, mutect2, varscan2
- GABRA1 | c.844A>T p.R282* | Nonsense Mutation (SNP) | VAF 89/273 reads (33%) | catalogued as COSV50098437; called by muse, mutect2, varscan2
- H2AC8 | c.227_229del p.K76del | In Frame Del (DEL) | VAF 132/321 reads (41%) | catalogued as rs780617468; called by pindel, varscan2
- HAUS5 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 211/568 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as rs574989910, COSV52548235; called by muse, mutect2, varscan2
- HDX | c.1568T>G p.L523R | Missense Mutation (SNP) | VAF 249/251 reads (99%) | SIFT tolerated (0.27); PolyPhen benign (0.203); catalogued as COSV52982960; called by muse, mutect2, varscan2
- HECW2 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 113/337 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs781563489; called by muse, mutect2, varscan2
- HLTF | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs1318653422; called by muse, mutect2, varscan2
- HTR1E | c.739T>G p.F247V | Missense Mutation (SNP) | VAF 161/351 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV59507370; called by muse, mutect2, varscan2
- IGHM | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 218/635 reads (34%) | SIFT deleterious (0.04); catalogued as rs1555378356; called by muse, mutect2, varscan2
- IL21R | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 37/462 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs374987749, COSV100559717; called by muse, mutect2
- IL2RB | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53427773; called by muse, mutect2
- IMPG2 | c.1600A>C p.S534R | Missense Mutation (SNP) | VAF 115/239 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV51986244, COSV99514564; called by muse, mutect2, varscan2
- IRAG2 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs1002749902; called by muse, mutect2
- KCNJ4 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 71/675 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.606); catalogued as COSV57856618; called by muse, mutect2, varscan2
- KMT2D | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM122087, CM146860, COSV99977967; called by mutect2, varscan2
- LIN7A | c.103T>G p.L35V | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54018274; called by muse, mutect2, varscan2
- LIPI | c.1412T>G p.L471R | Missense Mutation (SNP) | VAF 148/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100754048; called by muse, mutect2
- LRP10 | c.1357G>A p.G453S | Missense Mutation (SNP) | VAF 175/481 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs146378015; called by muse, mutect2, varscan2
- LRP1B | c.4850A>G p.E1617G | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1442498111, COSV67246049; called by muse, mutect2, varscan2
- MAPKBP1 | c.1843C>T p.R615W (on ENST00000456763 / NM_001128608.2; = p.R609W on NM_014994.3) | Missense Mutation (SNP) | VAF 134/429 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs918872385; called by muse, mutect2, varscan2
- MBL2 | c.410A>C p.K137T | Missense Mutation (SNP) | VAF 183/385 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100906255; called by muse, mutect2, varscan2
- MCOLN3 | c.832A>C p.I278L | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV62016425; called by muse, mutect2, varscan2
- MKI67 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 150/460 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767515257; called by muse, mutect2
- NEB | c.17387G>A p.R5796Q | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs775595412, COSV50842411, COSV51422946; called by muse, varscan2
- NUDT7 | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 134/283 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV51745802, COSV51745955; called by muse, mutect2, varscan2
- OR2M2 | c.926A>G p.K309R | Missense Mutation (SNP) | VAF 159/430 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV62897925, COSV62898897; called by muse, mutect2, varscan2
- OR4K5 | c.560T>A p.L187H | Missense Mutation (SNP) | VAF 145/449 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60003984, COSV60004319; called by muse, mutect2, varscan2
- PAK4 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 187/436 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs748729158; called by muse, mutect2, varscan2
- PCDH17 | c.2384C>A p.P795H | Missense Mutation (SNP) | VAF 200/572 reads (35%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); catalogued as COSV64977119; called by muse, mutect2, varscan2
- PCDHA9 | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 319/479 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as rs782709396, COSV65326472; called by muse, mutect2, varscan2
- PCDHB13 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs781868085, COSV99507096; called by muse, mutect2, varscan2
- PEAK1 | c.4513G>T p.E1505* | Nonsense Mutation (SNP) | VAF 137/410 reads (33%) | catalogued as COSV56931510; called by muse, mutect2, varscan2
- PIGO | c.1998G>T p.K666N | Missense Mutation (SNP) | VAF 308/602 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53053391; called by muse, mutect2
- PLSCR5 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 169/336 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs372370688, COSV71649018; called by muse, mutect2, varscan2
- PRDM9 | c.631T>A p.F211I | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV57003742; called by muse, mutect2
- PRRX1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 117/395 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs746264594; called by muse, mutect2, varscan2
- RASA3 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 156/476 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1053645877; called by muse, mutect2, varscan2
- RCVRN | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs771263915, COSV99874130; called by muse, mutect2, varscan2
- RGS4 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 148/260 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs771715416, COSV63357940; called by muse, mutect2, varscan2
- RIBC2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 58/686 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs559429477; called by muse, mutect2
- SEMA3G | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 142/461 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1353697063, COSV99202473; called by muse, mutect2, varscan2
- SH3D19 | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 159/331 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs1197857349, COSV100455479; called by muse, mutect2, varscan2
- SHROOM2 | c.3773C>T p.S1258L | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766057891; called by muse, mutect2, varscan2
- SLC8A2 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 34/756 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1176085653; called by muse, mutect2
- SPSB4 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 83/765 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1262932601; called by muse, mutect2, varscan2
- SUV39H1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 222/347 reads (64%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs368779259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.8034A>C p.E2678D (on ENST00000367255 / NM_182961.4; = p.E2685D on NM_033071.3) | Missense Mutation (SNP) | VAF 188/377 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.179); catalogued as rs1477042059; called by muse, mutect2, varscan2
- SYNE1 | c.2586A>C p.Q862H (on ENST00000367255 / NM_182961.4; = p.Q869H on NM_033071.3) | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99577190; called by muse, mutect2, varscan2
- SYNGAP1 | c.2742C>G p.D914E | Missense Mutation (SNP) | VAF 287/896 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.418); catalogued as COSV53386996; called by muse, mutect2, varscan2
- TECTA | c.6277G>A p.G2093R | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99081214; called by muse, mutect2, varscan2
- TENM3 | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs200031135; called by muse, mutect2
- TLL1 | c.1925A>C p.K642T | Missense Mutation (SNP) | VAF 155/382 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50263487, COSV50268157; called by muse, mutect2, varscan2
- TRIM49B | c.979A>C p.S327R | Missense Mutation (SNP) | VAF 193/523 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as COSV60321576, COSV60322163, COSV60324412; called by muse, mutect2, varscan2
- TRIM64B | c.1260dup p.D421* | Frame Shift Ins (INS) | VAF 193/776 reads (25%) | catalogued as rs748440706; called by mutect2, varscan2
- TRIML2 | c.1014A>C p.K338N | Missense Mutation (SNP) | VAF 284/574 reads (49%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as COSV58714561, COSV58718244, COSV58720356; called by muse, mutect2, varscan2
- TSNARE1 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 29/471 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs374432901; called by muse, mutect2
- UNC13A | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 22/439 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201058657, COSV53204237; called by muse, mutect2
- VPS13B | c.10183A>C p.S3395R | Missense Mutation (SNP) | VAF 114/280 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100664228; called by muse, mutect2, varscan2
- VPS13B | c.10309G>T p.A3437S | Missense Mutation (SNP) | VAF 182/387 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs879217228; called by muse, mutect2, varscan2
- WDR87 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454668933; called by muse, mutect2
- ZBTB38 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 161/433 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV58544579; called by muse, mutect2, varscan2
- ZFP28 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 71/794 reads (9%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1038560030, COSV56737228; called by muse, mutect2
- ZNF135 | c.932C>A p.S311Y (on ENST00000313434 / NM_001289401.2; = p.S323Y on NM_003436.4) | Missense Mutation (SNP) | VAF 252/465 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100536520; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3275T>C p.L1092P | Missense Mutation (SNP) | VAF 24/708 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ADGRB3 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 219/447 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- ANKLE1 | c.881G>T p.W294L (on ENST00000394458; = p.W240L on NM_152363.6) | Missense Mutation (SNP) | VAF 18/636 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.088); called by muse, mutect2
- ASMT | c.985T>C p.F329L (on ENST00000381229; = p.F357L on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 286/732 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AUTS2 | c.2003A>T p.K668M | Missense Mutation (SNP) | VAF 30/417 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CABIN1 | c.5734C>G p.L1912V | Missense Mutation (SNP) | VAF 68/661 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.137); called by muse, mutect2
- CCER1 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 69/580 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCL4 | c.216A>C p.Q72H | Missense Mutation (SNP) | VAF 48/575 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); called by muse, mutect2
- CD1A | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 236/478 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDH11 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- CDH7 | c.1715T>G p.L572R | Missense Mutation (SNP) | VAF 46/515 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP43 | c.3434T>G p.F1145C | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CHD6 | c.2632G>C p.D878H | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHST9 | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- CHUK | c.130_131del p.K44Vfs*17 | Frame Shift Del (DEL) | VAF 121/294 reads (41%) | called by mutect2, pindel, varscan2
- COL4A1 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 246/415 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- COL5A1 | c.4945T>G p.F1649V | Missense Mutation (SNP) | VAF 191/387 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CST5 | c.375A>C p.E125D | Missense Mutation (SNP) | VAF 25/255 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.069); called by muse, mutect2
- CYP19A1 | c.1216T>G p.F406V | Missense Mutation (SNP) | VAF 174/384 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- DDX53 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 70/375 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAJC13 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 31/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- DSEL | c.2502T>G p.S834R | Missense Mutation (SNP) | VAF 18/631 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.017); called by muse, mutect2
- EVC2 | c.340T>C p.S114P | Missense Mutation (SNP) | VAF 148/378 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, varscan2
- EVX2 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 100/884 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EYS | c.2287T>G p.W763G | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FAM71C | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 178/412 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2
- FAM9A | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 139/220 reads (63%) | called by muse, varscan2
- FIGN | c.206A>T p.K69I | Missense Mutation (SNP) | VAF 155/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GOLM2 | c.458_462del p.Y153Cfs*7 | Frame Shift Del (DEL) | VAF 109/315 reads (35%) | called by mutect2, pindel, varscan2
- GPHB5 | c.140A>C p.K47T | Missense Mutation (SNP) | VAF 172/415 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK1 | c.1541A>C p.N514T | Missense Mutation (SNP) | VAF 188/363 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GRK5 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 124/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTR3B | c.305A>T p.E102V | Missense Mutation (SNP) | VAF 148/466 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- HUWE1 | c.6899A>T p.E2300V | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KALRN | c.8250del p.T2751Hfs*5 (on ENST00000360013 / NM_001024660.4; = p.T1054Hfs*5 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 45/358 reads (13%) | called by mutect2, pindel, varscan2
- KCNA10 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 208/439 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNJ3 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 148/283 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KHDRBS3 | c.495A>T p.Q165H | Missense Mutation (SNP) | VAF 79/279 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- LOXHD1 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 214/423 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- LRFN5 | c.889A>G p.R297G | Missense Mutation (SNP) | VAF 203/427 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- LRIT2 | c.1169A>C p.K390T | Missense Mutation (SNP) | VAF 45/569 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- LRRN1 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 38/369 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MAP1B | c.2202G>T p.K734N | Missense Mutation (SNP) | VAF 46/503 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2
- MBD6 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 74/750 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2
- MINDY4B | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT tolerated, low confidence (0.78); PolyPhen possibly damaging (0.737); called by muse, mutect2
- MSH4 | c.2227A>T p.I743L | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2
- MTHFD1L | c.825A>C p.E275D | Missense Mutation (SNP) | VAF 100/272 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NAV3 | c.1673A>C p.K558T | Missense Mutation (SNP) | VAF 196/463 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- NLGN4Y | c.2071T>G p.L691V | Missense Mutation (SNP) | VAF 181/245 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NLRP6 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 268/816 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, varscan2
- NMBR | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPAS3 | c.2447C>T p.T816I (on ENST00000356141 / NM_001164749.2; = p.T784I on NM_022123.3) | Missense Mutation (SNP) | VAF 48/651 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); called by muse, mutect2
- OAZ1 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 215/445 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OBSCN | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 227/587 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OBSCN | c.10259G>A p.C3420Y | Missense Mutation (SNP) | VAF 116/424 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- OLIG1 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 139/441 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- OR10C1 | c.668T>C p.L223P (on ENST00000622521; = p.L221P on NM_013941.3) | Missense Mutation (SNP) | VAF 367/766 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- OR14A2 | c.736T>G p.F246V | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); called by mutect2, varscan2
- OR2A25 | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 192/400 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR52K2 | c.689T>G p.L230R | Missense Mutation (SNP) | VAF 138/396 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PABPC4L | c.1069T>G p.L357V | Missense Mutation (SNP) | VAF 172/345 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- POSTN | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 101/233 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R3A | c.584T>G p.V195G | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF4 | c.1415A>T p.E472V | Missense Mutation (SNP) | VAF 107/336 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2
- PRDM9 | c.846A>C p.E282D | Missense Mutation (SNP) | VAF 193/444 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PREX2 | c.3674T>A p.L1225H | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTCHD3 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 68/676 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PTPRQ | c.1423A>C p.K475Q (on ENST00000616559; = p.K433Q on NM_001145026.2) | Missense Mutation (SNP) | VAF 150/300 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, varscan2
- RC3H2 | c.3291G>A p.M1097I | Missense Mutation (SNP) | VAF 54/572 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- RCSD1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 181/543 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUNX1 | c.152T>C p.M51T (on ENST00000344691 / NM_001001890.3; = p.M78T on NM_001754.5) | Missense Mutation (SNP) | VAF 39/906 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); called by muse, mutect2
- SCN1A | c.5227C>A p.P1743T (on ENST00000303395 / NM_001202435.3; = p.P1732T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- SGCZ | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOS2 | c.3471T>G p.H1157Q | Missense Mutation (SNP) | VAF 113/260 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31A1 | c.1929G>A p.W643* | Nonsense Mutation (SNP) | VAF 96/1290 reads (7%) | called by muse, mutect2
- STK33 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 143/296 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TPK1 | c.727A>C p.S243R | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPO | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 74/750 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.022); called by muse, mutect2
- TTN | c.6071A>T p.D2024V (on ENST00000591111; = p.D1978V on NM_003319.4) | Missense Mutation (SNP) | VAF 44/550 reads (8%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- TUT4 | c.3470T>G p.V1157G | Missense Mutation (SNP) | VAF 118/271 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- UNC13B | c.4703G>A p.R1568K | Missense Mutation (SNP) | VAF 267/541 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- WNT9B | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 295/792 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED1 | c.1640_1682del p.M547Rfs*12 | Frame Shift Del (DEL) | VAF 315/860 reads (37%) | called by mutect2, pindel, varscan2
- ZIC1 | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); called by muse, mutect2
- ZNF416 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 181/371 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF527 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 19/446 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- ZNF705A | c.222A>T p.Q74H | Missense Mutation (SNP) | VAF 129/466 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZW10 | c.101_102insA p.K35Qfs*3 | Frame Shift Ins (INS) | VAF 167/421 reads (40%) | called by mutect2, pindel, varscan2
- AARS2 | c.21T>A p.A7= | Silent (SNP) | VAF 241/613 reads (39%) | catalogued as COSV55114501; called by muse, mutect2, varscan2
- ABCA4 | c.5721C>T p.A1907= | Silent (SNP) | VAF 84/302 reads (28%) | catalogued as rs368502305; called by muse, mutect2
- ADAMTSL1 | c.3024G>A p.A1008= | Silent (SNP) | VAF 68/898 reads (8%) | catalogued as rs1264442007, COSV65902628; called by muse, mutect2
- ADIPOR2 | c.363C>T p.L121= | Silent (SNP) | VAF 41/365 reads (11%) | catalogued as COSV63947721; called by muse, mutect2, varscan2
- ATP13A5 | c.1188C>T p.S396= | Silent (SNP) | VAF 52/600 reads (9%) | catalogued as rs779145810, COSV60867433; called by muse, mutect2
- BARX1 | c.36C>T p.F12= | Silent (SNP) | VAF 26/313 reads (8%) | called by muse, mutect2
- CAPN9 | c.1344G>A p.T448= | Silent (SNP) | VAF 193/365 reads (53%) | catalogued as rs763285582; called by muse, mutect2, varscan2
- CNTNAP3 | c.3003C>T p.S1001= | Silent (SNP) | VAF 129/1176 reads (11%) | catalogued as rs1256433400; called by muse, mutect2, varscan2
- COL4A5 | c.2277T>G p.P759= | Silent (SNP) | VAF 243/244 reads (100%) | catalogued as rs1415670653; called by muse, mutect2, varscan2
- COL6A6 | c.5670G>A p.A1890= | Silent (SNP) | VAF 163/461 reads (35%) | catalogued as COSV62023642; called by muse, mutect2, varscan2
- CPN1 | c.1227G>A p.T409= | Silent (SNP) | VAF 15/229 reads (7%) | catalogued as rs1440201476, COSV64942125; called by muse, mutect2
- CSMD1 | c.1959T>A p.G653= (on ENST00000520002; = p.G652= on NM_033225.6) | Silent (SNP) | VAF 154/468 reads (33%) | called by muse, mutect2, varscan2
- DDI1 | c.852A>G p.R284= | Silent (SNP) | VAF 245/545 reads (45%) | called by muse, mutect2, varscan2
- DNAH2 | c.12714G>A p.P4238= | Silent (SNP) | VAF 22/270 reads (8%) | catalogued as rs776139568; called by muse, mutect2
- EFL1 | c.2742A>C p.G914= | Silent (SNP) | VAF 24/503 reads (5%) | called by muse, mutect2
- ERC2 | c.2499A>G p.K833= | Silent (SNP) | VAF 48/518 reads (9%) | called by muse, mutect2
- EYS | c.2052G>A p.E684= | Silent (SNP) | VAF 119/350 reads (34%) | called by muse, mutect2, varscan2
- FHOD3 | c.711G>A p.T237= | Silent (SNP) | VAF 37/336 reads (11%) | catalogued as rs753187423, COSV57169797; called by muse, mutect2, varscan2
- FLG | c.10221T>C p.T3407= | Silent (SNP) | VAF 81/690 reads (12%) | catalogued as rs1430005853; called by muse, mutect2, varscan2
- FOXL2 | c.648C>T p.A216= | Silent (SNP) | VAF 311/629 reads (49%) | catalogued as rs975695593; called by muse, mutect2, varscan2
- GATA5 | c.60C>A p.G20= | Silent (SNP) | VAF 64/642 reads (10%) | called by muse, mutect2
- GSG1L | c.279C>T p.D93= | Silent (SNP) | VAF 51/471 reads (11%) | called by muse, varscan2
- HERC1 | c.11382C>G p.T3794= | Silent (SNP) | VAF 112/318 reads (35%) | called by muse, mutect2, varscan2
- IGHG3 | c.1308C>T p.P436= | Silent (SNP) | VAF 200/441 reads (45%) | catalogued as rs945735123; called by muse, mutect2, varscan2
- ITIH5 | c.1233C>T p.V411= | Silent (SNP) | VAF 48/592 reads (8%) | catalogued as rs781569747, COSV53662512; called by muse, mutect2
- KIAA0753 | c.2325G>A p.L775= | Silent (SNP) | VAF 136/368 reads (37%) | called by muse, mutect2, varscan2
- KIAA1755 | c.1911C>T p.D637= | Silent (SNP) | VAF 46/492 reads (9%) | catalogued as rs112826952; called by muse, mutect2
- KIR3DL2 | c.276C>T p.T92= | Silent (SNP) | VAF 66/335 reads (20%) | called by muse, mutect2, varscan2
- L3MBTL4 | c.1617A>G p.Q539= | Silent (SNP) | VAF 146/352 reads (41%) | catalogued as COSV53111923, COSV53123052; called by muse, mutect2, varscan2
- MDGA2 | c.2770C>T p.L924= (on ENST00000399232 / NM_001113498.2; = p.L626= on NM_182830.4) | Silent (SNP) | VAF 66/227 reads (29%) | catalogued as COSV62120013; called by muse, mutect2, varscan2
- MRNIP | c.987A>T p.L329= | Silent (SNP) | VAF 163/481 reads (34%) | called by muse, mutect2, varscan2
- MUC4 | c.7260C>T p.T2420= | Silent (SNP) | VAF 254/2740 reads (9%) | catalogued as rs552051914; called by muse, mutect2
- MUC6 | c.2382C>T p.T794= | Silent (SNP) | VAF 201/402 reads (50%) | catalogued as rs751069493; called by muse, varscan2
- MYH9 | c.279C>T p.N93= | Silent (SNP) | VAF 28/466 reads (6%) | catalogued as rs121913655, CM002369, COSV99337612; called by muse, mutect2
- OBSCN | c.18267G>A p.A6089= | Silent (SNP) | VAF 253/546 reads (46%) | catalogued as rs759601682; called by muse, mutect2, varscan2
- ODC1 | c.924G>A p.E308= | Silent (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- OR5T3 | c.600T>G p.S200= | Silent (SNP) | VAF 48/616 reads (8%) | catalogued as COSV100282706, COSV57379270; called by muse, mutect2
- PACS1 | c.2199G>A p.R733= | Silent (SNP) | VAF 32/380 reads (8%) | catalogued as rs369077872; called by muse, mutect2
- PALMD | c.1062G>A p.S354= | Silent (SNP) | VAF 44/532 reads (8%) | catalogued as rs374387839; called by muse, mutect2
- PCDHB6 | c.1341C>T p.P447= | Silent (SNP) | VAF 384/773 reads (50%) | catalogued as COSV50700539; called by muse, mutect2, varscan2
- PIEZO2 | c.988C>T p.L330= | Silent (SNP) | VAF 36/599 reads (6%) | called by muse, mutect2
- PKHD1L1 | c.6564A>G p.G2188= | Silent (SNP) | VAF 44/468 reads (9%) | catalogued as rs769223422, COSV65737892; called by muse, mutect2
- PRAMEF14 | c.960T>G p.G320= | Silent (SNP) | VAF 41/441 reads (9%) | called by muse, mutect2, varscan2
- PTCH1 | c.3669G>A p.S1223= | Silent (SNP) | VAF 235/639 reads (37%) | catalogued as rs780515178, COSV100108119; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RGPD2 | c.42G>A p.S14= | Silent (SNP) | VAF 37/495 reads (7%) | catalogued as COSV59530942; called by muse, mutect2
- RGS12 | c.1389G>A p.R463= | Silent (SNP) | VAF 88/681 reads (13%) | catalogued as COSV60907081; called by muse, mutect2, varscan2
- RYR3 | c.9165C>T p.A3055= (on ENST00000389232; = p.A3056= on NM_001036.6) | Silent (SNP) | VAF 40/385 reads (10%) | called by muse, mutect2, varscan2
- SHANK3 | c.3456G>A p.P1152= | Silent (SNP) | VAF 340/675 reads (50%) | catalogued as rs764295916; called by muse, mutect2, varscan2
- TG | c.2433A>G p.E811= | Silent (SNP) | VAF 280/514 reads (54%) | catalogued as COSV55088246; called by muse, mutect2, varscan2
- TMTC2 | c.1443A>G p.E481= | Silent (SNP) | VAF 153/317 reads (48%) | catalogued as COSV58268096; called by muse, mutect2, varscan2
- TRAK2 | c.2733G>A p.L911= | Silent (SNP) | VAF 140/346 reads (40%) | called by muse, mutect2
- TRIM48 | c.69A>G p.Q23= | Silent (SNP) | VAF 180/333 reads (54%) | catalogued as COSV101338206; called by muse, mutect2, varscan2
- TTN | c.25407T>C p.S8469= (on ENST00000591111; = p.S7542= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 154/417 reads (37%) | catalogued as COSV59870414; called by muse, mutect2, varscan2
- UBAC1 | c.1017C>T p.G339= | Silent (SNP) | VAF 156/571 reads (27%) | called by muse, mutect2, varscan2
- UBXN2B | c.882G>A p.A294= | Silent (SNP) | VAF 112/366 reads (31%) | catalogued as rs775165230; called by muse, mutect2, varscan2
- ZNF521 | c.3279T>C p.C1093= | Silent (SNP) | VAF 60/674 reads (9%) | called by muse, mutect2
- ATRIP | c.*1046C>A | 3'UTR (SNP) | VAF 252/550 reads (46%) | called by mutect2, varscan2
- CSMD3 | c.*1643G>C | 3'UTR (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-35+854G>T | Intron (SNP) | VAF 25/628 reads (4%) | called by muse, mutect2
- KCNQ1 | c.1514+25103del | Intron (DEL) | VAF 184/461 reads (40%) | called by mutect2, pindel, varscan2
- KIAA1328 | c.1232+16661T>C | Intron (SNP) | VAF 32/346 reads (9%) | called by muse, mutect2
- LCORL | chr4:17876117 C>T | 3'Flank (SNP) | VAF 34/380 reads (9%) | catalogued as rs934012587; called by muse, mutect2
- LRRFIP1 | c.154-1736G>A | Intron (SNP) | VAF 15/440 reads (3%) | called by muse, mutect2
- MASP1 | c.1303+5759T>C | Intron (SNP) | VAF 197/383 reads (51%) | called by muse, mutect2, varscan2
- NEB | c.8889+544G>T | Intron (SNP) | VAF 167/328 reads (51%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248441651 T>C | 5'Flank (SNP) | VAF 155/498 reads (31%) | called by muse, mutect2, varscan2
- PDHA1 | c.57+2517T>G | Intron (SNP) | VAF 20/227 reads (9%) | called by muse, mutect2
- PEX16 | c.*144G>A | 3'UTR (SNP) | VAF 222/436 reads (51%) | catalogued as rs751522221; called by muse, mutect2, varscan2
- TBC1D32 | c.2571-9398T>A | Intron (SNP) | VAF 83/260 reads (32%) | called by muse, mutect2, varscan2
- TPM4 | c.*138G>A | 3'UTR (SNP) | VAF 40/380 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.34523-902A>C | Intron (SNP) | VAF 23/422 reads (5%) | catalogued as rs554529099; called by muse, mutect2
